TARGET case TARGET-15-SJMPAL012427 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a018a6bf-9e9c-4076-9e2e-7916c17483ce

Demographics
Sex at birth: female; Age at index: 16 years; Vital status: Dead; Days to death: 162 days.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 16.2 years (5,915 days); Year of diagnosis: 1997; Days to last follow up: 162 days.

Follow-up (1 entry)
- Days to follow up: 162 days; Event-free: no event (relapse, second malignancy or death) recorded through day 162; Year of follow up: 1997.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 2.7 ×10³/µL.

Biospecimens (2 samples)
- Sample TARGET-15-SJMPAL012427-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL012427-14A.1: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 162
- Protocol: St. Jude
- WBC at Diagnosis: 2.7
- Karyotype: 46,XX,der(2)t(2;14)(q21;q32),add(5)(q31),der(14)ins(14;2)(q22;q21q37)[15]/46,XX[6]
- WHO ALAL Classification: T/M
- WHO Dx: T/M
